Somatic mutation profile of tumor specimen MMRF_1407_3_BM_CD138pos (aliquot MMRF_1407_3_BM_CD138pos_T1_KBS5U_K11918) from MMRF case MMRF_1407, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.7 years (26,206 days).
Specimen MMRF_1407_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) feb74198-0e21-4fc8-8b68-9f1136c3d3b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1407_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1407_1_PB_Whole_C4_KBS5U_K11891; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a4de52d-472d-4b52-88cc-fbb8c52de154

The open-access MAF lists 18 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 8, Intron 3, Missense Mutation 3, Silent 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30B | c.4052T>A p.V1351E | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, mutect2
- OGT | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.927); called by muse, mutect2
- SENP1 | c.914T>C p.L305S | Missense Mutation (SNP) | VAF 5/136 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- SIGMAR1 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- OGT | c.240G>T p.L80= | Silent (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- TNXB | c.10893C>T p.S3631= (on ENST00000647633; = p.S3384= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/160 reads (4%) | called by muse, mutect2
- B3GALT1 | c.*273T>A | 3'UTR (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- GPR107 | c.*2019G>A | 3'UTR (SNP) | VAF 7/117 reads (6%) | catalogued as rs1483784346; called by muse, mutect2
- GRHL2 | c.*446G>A | 3'UTR (SNP) | VAF 5/120 reads (4%) | called by muse, mutect2
- HOXA2 | c.392-180C>T | Intron (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- HRNR | c.*870G>C | 3'UTR (SNP) | VAF 4/96 reads (4%) | called by muse, mutect2
- NREP | c.*622A>G | 3'UTR (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- PIK3AP1 | c.2241+139A>C | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- PIK3R1 | c.*1469T>G | 3'UTR (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- RGS5 | c.*1158T>C | 3'UTR (SNP) | VAF 10/141 reads (7%) | called by muse, mutect2
- TMSB4X | c.-45G>C | 5'UTR (SNP) | VAF 4/67 reads (6%) | called by muse, mutect2
- XIRP2 | c.*1485C>T | 3'UTR (SNP) | VAF 12/372 reads (3%) | called by muse, mutect2
- XKR4 | c.806+61124C>T | Intron (SNP) | VAF 11/301 reads (4%) | called by muse, mutect2
